Gene-level copy-number profile of tumor specimen TCGA-2G-AALF-01A from TCGA case TCGA-2G-AALF, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Tissue or organ of origin: Testis, NOS.
Specimen TCGA-2G-AALF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.9fed0f67-f528-42bd-b176-64412c30019b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2G-AALF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e8952b9-860f-4057-840f-27a65365a106

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 7,257; copy number 3: 28,528; copy number 4: 17,941; copy number 5: 4,140; copy number 6: 320; copy number 7: 197; copy number 8: 1,434.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2G-AALF-01A-11D-A42X-01): tumor purity 0.66, ploidy 3.38, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,631 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:14,489,107–34,694,174, 247 genes, copy number 7–8 (broad region; genes not listed).
- chr12:66,767–41,774,671, 897 genes, copy number 8 (broad region; genes not listed).
- chr12:69,713,633–73,208,317, 47 genes, copy number 8: AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1.
- chr16:55,389,700–55,506,691, 1 gene, copy number 8 (within-gene range 3–8): MMP2.
- chr16:55,426,797–71,578,187, 439 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
